Somatic mutation profile of tumor specimen TCGA-VQ-AA6B-01A (aliquot TCGA-VQ-AA6B-01A-11D-A410-08) from TCGA case TCGA-VQ-AA6B, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 48.9 years (17,852 days).
Specimen TCGA-VQ-AA6B-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d18232b9-2398-4d9c-8420-b87c64dec672.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VQ-AA6B-10A (Blood Derived Normal), aliquot TCGA-VQ-AA6B-10A-01D-A413-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/64b0bb6d-d442-46c2-8d22-8b65ca5517dc

The open-access MAF lists 85 somatic variants for this specimen: 70 protein-altering or splice-affecting, 13 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 13, Frame Shift Del 6, Nonsense Mutation 5, Splice Site 2, In Frame Ins 1, 3'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.814G>A p.V272M | Missense Mutation (SNP) | VAF 8/11 reads (73%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912657, CM130241, CM920676, COSV52661812, COSV52677483, COSV52701127; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2
- A1CF | c.1115C>T p.A372V | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.024); catalogued as COSV99257740; called by muse, mutect2, varscan2
- ADARB2 | c.2108C>T p.A703V | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.494); catalogued as rs751820473, COSV67182195; called by muse, mutect2, varscan2
- AL035460.1 | c.197C>A p.S66Y | Missense Mutation (SNP) | VAF 24/237 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.178); catalogued as COSV100730125, COSV63028599; called by muse, mutect2, varscan2
- ARAP3 | c.3331G>A p.V1111M | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.163); catalogued as COSV53356685; called by muse, mutect2, varscan2
- ARHGEF28 | c.965G>A p.R322H | Missense Mutation (SNP) | VAF 48/98 reads (49%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs557233944, COSV99710089; called by muse, mutect2, varscan2
- ASPM | c.3723T>G p.N1241K | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99661113; called by muse, mutect2, varscan2
- ATP6V0A2 | c.1981C>T p.P661S | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100377161; called by muse, mutect2, varscan2
- ATP8A2 | c.2836C>T p.L946F | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99684236; called by muse, mutect2, varscan2
- BIRC6 | c.12951G>C p.E4317D | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101428875; called by muse, mutect2, varscan2
- BNC2 | c.1867C>G p.P623A | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1217159961, COSV101034400, COSV66156073; called by muse, mutect2, varscan2
- C9orf43 | c.820C>T p.R274* | Nonsense Mutation (SNP) | VAF 14/82 reads (17%) | catalogued as rs201215268, COSV55912837; called by muse, mutect2, varscan2
- CCNL2 | c.600C>G p.I200M | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101275732, COSV68767163; called by muse, mutect2
- CD44 | c.337C>T p.Q113* | Nonsense Mutation (SNP) | VAF 36/89 reads (40%) | catalogued as COSV99556795; called by muse, mutect2, varscan2
- CDK14 | c.1274G>A p.R425Q (on ENST00000380050 / NM_001287135.2; = p.R407Q on NM_012395.3) | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (1); PolyPhen probably damaging (0.921); catalogued as rs546258215, COSV56053031; called by muse, mutect2, varscan2
- COL1A2 | c.125G>T p.G42V | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99801073; called by muse, mutect2, varscan2
- CRPPA | c.1114_1116dup p.V372dup (on ENST00000407010 / NM_001368197.1; = p.V322dup on NM_001101417.4) | In Frame Ins (INS) | VAF 7/28 reads (25%) | catalogued as rs587777798; called by mutect2, varscan2
- CYFIP1 | c.1490G>A p.R497Q | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.39); catalogued as rs1351179231; called by muse, mutect2, varscan2
- CYP27A1 | c.273G>C p.K91N | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.088); catalogued as COSV99298752; called by muse, mutect2, varscan2
- DCLRE1A | c.1114G>C p.D372H | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV100800490; called by muse, mutect2, varscan2
- DDX43 | c.1475T>C p.V492A | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as COSV64813759; called by muse, mutect2, varscan2
- DNAH3 | c.10753G>A p.A3585T | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs760935801, COSV99770584; called by muse, mutect2, varscan2
- DNAH9 | c.5656G>A p.A1886T | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1309622977, COSV52334000; called by muse, mutect2, varscan2
- ESRP1 | c.71G>C p.G24A | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV100619638; called by muse, mutect2, varscan2
- FLG | c.10619G>T p.S3540I | Missense Mutation (SNP) | VAF 36/232 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs1281355725, COSV100912188; called by muse, varscan2
- FRMPD2 | c.2099G>A p.S700N | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.151); catalogued as COSV100564189; called by muse, mutect2, varscan2
- GABRB2 | c.1228G>C p.E410Q (on ENST00000274547; = p.E372Q on NM_000813.3) | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.866); catalogued as COSV99196631; called by muse, mutect2, varscan2
- HELZ2 | c.233A>G p.H78R | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.109); catalogued as rs1310382868, COSV100915701; called by muse, mutect2
- KHK | c.233G>A p.R78Q | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV99566538; called by muse, mutect2
- KRT32 | c.365C>T p.A122V | Missense Mutation (SNP) | VAF 53/645 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.26); catalogued as rs370354142; called by muse, mutect2
- LAMP1 | c.508C>A p.L170I | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.446); catalogued as COSV100208773; called by muse, mutect2
- LIG4 | c.1188T>G p.I396M | Missense Mutation (SNP) | VAF 23/109 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.062); catalogued as COSV100800065; called by muse, mutect2, varscan2
- LRP1B | c.5603A>C p.Q1868P | Missense Mutation (SNP) | VAF 22/146 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as COSV101260930; called by muse, mutect2, varscan2
- LRP1B | c.1208del p.N403Ifs*17 | Frame Shift Del (DEL) | VAF 18/130 reads (14%) | catalogued as COSV67205391; called by mutect2, pindel, varscan2
- LRRC30 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.64); PolyPhen benign (0.024); catalogued as COSV67301271; called by muse, mutect2, varscan2
- LRRC57 | c.218_221del p.K73Rfs*11 | Frame Shift Del (DEL) | VAF 12/36 reads (33%) | catalogued as rs1279957715, COSV53001553; called by mutect2, pindel, varscan2
- MED1 | c.1694A>T p.N565I | Missense Mutation (SNP) | VAF 28/408 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.018); catalogued as COSV100328158; called by muse, mutect2
- MS4A13 | c.187-1G>T p.X63_splice | Splice Site (SNP) | VAF 33/82 reads (40%) | catalogued as COSV100981211; called by muse, mutect2, varscan2
- MS4A14 | c.2012T>G p.L671R | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.879); catalogued as COSV100280097; called by muse, mutect2, varscan2
- NBEA | c.1466T>G p.I489S | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100084123; called by muse, mutect2
- NELL2 | c.1340G>A p.G447E | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.997); catalogued as COSV100420810; called by muse, mutect2, varscan2
- OAS2 | c.1630C>T p.R544C | Missense Mutation (SNP) | VAF 44/182 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1387011544, COSV60801967, COSV60803423; called by muse, mutect2, varscan2
- OR51I2 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 57/132 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs752205284, COSV58298032, COSV58300003; called by muse, mutect2, varscan2
- OR5B17 | c.254T>C p.I85T | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs1452660871, COSV100641959; called by muse, mutect2, varscan2
- PCDHGB2 | c.1630G>A p.A544T | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.379); catalogued as rs1328174006, COSV99533891; called by muse, mutect2, varscan2
- PER2 | c.2455G>A p.A819T | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as rs199933426, COSV54525000; called by muse, mutect2
- PIK3C2G | c.3394C>T p.H1132Y (on ENST00000676171; = p.H1091Y on NM_004570.5) | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.293); catalogued as rs919587913, COSV99853956; called by muse, mutect2, varscan2
- PLCH1 | c.268G>T p.D90Y (on ENST00000340059 / NM_001130960.2; = p.D102Y on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100398213; called by muse, mutect2, varscan2
- PTCHD4 | c.1462G>A p.G488R | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs763241410, COSV100261637; called by muse, mutect2, varscan2
- PTGIS | c.1222C>T p.R408* | Nonsense Mutation (SNP) | VAF 24/60 reads (40%) | catalogued as rs774604774, COSV99721297; called by muse, mutect2, varscan2
- RAB3GAP2 | c.296T>A p.F99Y | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.51); catalogued as COSV99424998; called by muse, mutect2, varscan2
- RANBP2 | c.7142G>T p.C2381F | Missense Mutation (SNP) | VAF 113/637 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99313249; called by muse, mutect2, varscan2
- RPTOR | c.2242+2T>G p.X748_splice | Splice Site (SNP) | VAF 37/152 reads (24%) | catalogued as COSV100157250; called by muse, mutect2, varscan2
- SIGLEC1 | c.250C>T p.R84C | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs140311277; called by muse, mutect2, varscan2
- SLC36A3 | c.1378C>T p.H460Y | Missense Mutation (SNP) | VAF 53/99 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs532280240, COSV100077888; called by muse, mutect2, varscan2
- SLITRK5 | c.403C>A p.H135N | Missense Mutation (SNP) | VAF 20/132 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100281195, COSV61524889; called by muse, mutect2, varscan2
- TBC1D32 | c.2702C>T p.P901L | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99251286; called by muse, mutect2, varscan2
- TBL1Y | c.1400T>A p.L467* | Nonsense Mutation (SNP) | VAF 20/30 reads (67%) | catalogued as COSV100667365; called by muse, mutect2, varscan2
- TMEM196 | c.285G>C p.K95N | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV101337519, COSV101337526; called by muse, mutect2, varscan2
- TRDN | c.101G>C p.R34T | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.963); catalogued as COSV100523382; called by muse, mutect2, varscan2
- UBE2R2 | c.284C>T p.S95L | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54287534; called by muse, mutect2, varscan2
- UBR4 | c.14717G>A p.S4906N | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV100921855; called by muse, mutect2, varscan2
- VAV3 | c.2231A>T p.E744V | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as COSV100580372; called by muse, mutect2, varscan2
- XXYLT1 | c.714G>T p.L238F | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100118738; called by muse, mutect2
- YES1 | c.1160T>G p.I387S | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV100099945; called by muse, mutect2
- ZNF532 | c.470C>G p.S157* | Nonsense Mutation (SNP) | VAF 22/78 reads (28%) | catalogued as COSV100267157; called by muse, mutect2, varscan2
- KATNA1 | c.806del p.T269Nfs*10 | Frame Shift Del (DEL) | VAF 15/84 reads (18%) | called by mutect2, pindel, varscan2
- LBR | c.188_191del p.R63Kfs*54 | Frame Shift Del (DEL) | VAF 7/33 reads (21%) | called by mutect2, pindel, varscan2
- PCF11 | c.301_304del p.I101Vfs*27 | Frame Shift Del (DEL) | VAF 9/35 reads (26%) | called by pindel, varscan2
- UGT2A1 | c.1110del p.T371Lfs*34 | Frame Shift Del (DEL) | VAF 18/32 reads (56%) | called by mutect2, pindel, varscan2
- APLNR | c.138C>T p.N46= | Silent (SNP) | VAF 8/92 reads (9%) | catalogued as rs138964036; called by muse, mutect2
- CDC6 | c.1449G>A p.G483= | Silent (SNP) | VAF 30/614 reads (5%) | catalogued as COSV99266680; called by muse, mutect2
- CORO2A | c.993C>T p.D331= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as rs1241496233, COSV100674141; called by muse, mutect2, varscan2
- DOCK4 | c.4977G>A p.G1659= | Silent (SNP) | VAF 101/186 reads (54%) | catalogued as rs755452247, COSV70238736; called by muse, mutect2, varscan2
- GRID2 | c.909T>C p.H303= | Silent (SNP) | VAF 29/95 reads (31%) | catalogued as COSV56223717, COSV99946779; called by muse, mutect2, varscan2
- INAVA | c.780C>T p.L260= | Silent (SNP) | VAF 26/79 reads (33%) | catalogued as COSV100950119; called by muse, mutect2, varscan2
- KCNG1 | c.15G>A p.P5= | Silent (SNP) | VAF 5/77 reads (6%) | catalogued as rs913335879, COSV100857177; called by muse, mutect2
- KRTAP17-1 | c.306C>T p.C102= | Silent (SNP) | VAF 11/284 reads (4%) | catalogued as rs1200879338, COSV100498596; called by muse, mutect2
- MRGPRX4 | c.597G>A p.L199= | Silent (SNP) | VAF 17/106 reads (16%) | catalogued as COSV100049846; called by muse, mutect2, varscan2
- PHF20L1 | c.1119A>G p.E373= | Silent (SNP) | VAF 35/144 reads (24%) | catalogued as rs757244474, COSV99622154; called by muse, mutect2, varscan2
- RNF40 | c.1074C>T p.A358= | Silent (SNP) | VAF 19/116 reads (16%) | catalogued as rs368724386, COSV100222325; called by muse, mutect2, varscan2
- TMEM214 | c.933C>T p.G311= | Silent (SNP) | VAF 21/140 reads (15%) | catalogued as COSV99476526; called by muse, mutect2, varscan2
- UNC45B | c.486C>A p.L162= | Silent (SNP) | VAF 4/60 reads (7%) | catalogued as COSV52099435; called by muse, mutect2
- AL109984.1 | n.186+1309C>T | Intron (SNP) | VAF 55/102 reads (54%) | catalogued as rs562200956, COSV100802012; called by muse, mutect2, varscan2
- MIR1270 | chr19:20397381 A>T | 3'Flank (SNP) | VAF 14/50 reads (28%) | catalogued as rs1197756085; called by muse, mutect2, varscan2
